Somatic mutation profile of tumor specimen ALCH-AEF6-TTP1-A (aliquot ALCH-AEF6-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AEF6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.1 years (20,852 days).
Specimen ALCH-AEF6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 708f43ca-a2a3-4f7d-b244-e2e76989ab45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEF6-NB1-A (Blood Derived Normal), aliquot ALCH-AEF6-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5e00ad1-643a-49cc-bec1-f66eedc83d25

The open-access MAF lists 176 somatic variants for this specimen: 131 protein-altering or splice-affecting, 25 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 25, Intron 10, Nonsense Mutation 9, Splice Site 7, RNA 4, Splice Region 3, 5'UTR 2, Frame Shift Del 2, Translation Start Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 694/1679 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 53/712 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- A2M | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 29/500 reads (6%) | catalogued as COSV59388760, COSV59389701; called by muse, mutect2
- BAP1 | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 11/169 reads (7%) | catalogued as COSV56238233; called by muse, mutect2
- CBX6 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.106); catalogued as COSV99328092; called by muse, mutect2
- CD5L | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 55/556 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs751994649; called by muse, mutect2
- COL22A1 | c.2558C>A p.T853N | Missense Mutation (SNP) | VAF 30/503 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.688); catalogued as COSV57364440; called by muse, mutect2
- CSMD3 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 101/657 reads (15%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.942); catalogued as COSV52091224, COSV99821814; called by muse, mutect2, varscan2
- CYP2C9 | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 70/1050 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV53248986; called by muse, mutect2
- DCAF8L1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 9/243 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs1477465033; called by muse, mutect2
- DUSP26 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV56361401; called by muse, mutect2
- ELF1 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV53503847; called by muse, mutect2
- FLRT2 | c.1323G>T p.W441C | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58150425; called by muse, mutect2
- FMR1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 22/738 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54423059; called by muse, mutect2
- FNDC1 | c.1379C>A p.A460E | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.069); catalogued as rs773772923, COSV51947941, COSV99794933; called by muse, mutect2, varscan2
- HCRTR2 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 83/1012 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV100904485, COSV63797697; called by muse, mutect2
- HHLA1 | c.366T>A p.I122= | Splice Region (SNP) | VAF 49/274 reads (18%) | catalogued as COSV70153617; called by muse, mutect2, varscan2
- HSPA8 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); catalogued as COSV57084081; called by muse, mutect2
- IQGAP3 | c.4783G>T p.D1595Y | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63251244, COSV63253208; called by muse, mutect2, varscan2
- IRAK1 | c.910-1G>T p.X304_splice | Splice Site (SNP) | VAF 14/158 reads (9%) | catalogued as COSV57651805; called by muse, mutect2
- KANK1 | c.3552C>T p.A1184= | Splice Region (SNP) | VAF 26/291 reads (9%) | catalogued as rs766169056; called by muse, mutect2
- KCNH7 | c.2234C>A p.A745D | Missense Mutation (SNP) | VAF 86/1082 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59801226; called by muse, mutect2
- LPA | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 36/564 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.868); catalogued as rs761873886; called by muse, mutect2, varscan2
- LRRC66 | c.2243C>A p.T748K | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs761786030; called by muse, mutect2
- MAEL | c.537C>G p.H179Q | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764537957; called by muse, mutect2, varscan2
- MME | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 31/506 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV64711464; called by muse, mutect2
- MYO15A | c.2199del p.D734Tfs*3 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs1555539272; called by mutect2, pindel, varscan2
- NEK10 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774892094; called by muse, mutect2
- NRXN2 | c.2617G>A p.V873M | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as COSV99634793; called by muse, mutect2
- OR4C15 | c.595G>T p.G199W (on ENST00000314644; = p.G145W on NM_001001920.2) | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs371985507, COSV100115723, COSV58955567; called by muse, mutect2, varscan2
- PCDH11X | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 40/590 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100008851; called by muse, mutect2
- PCDHGA3 | c.1010T>C p.V337A | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV54013565; called by muse, mutect2
- RGS7 | c.1175G>C p.G392A | Missense Mutation (SNP) | VAF 86/731 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs762316382, COSV100467385; called by muse, mutect2, varscan2
- ROBO4 | c.2627G>T p.G876V | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60628640; called by muse, mutect2
- RYR2 | c.4193G>T p.S1398I | Missense Mutation (SNP) | VAF 54/592 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.676); catalogued as COSV63669437; called by muse, mutect2
- SCFD2 | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs979515257; called by muse, mutect2
- TMPRSS15 | c.2054C>G p.T685R | Missense Mutation (SNP) | VAF 70/938 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV53034292, COSV53035773; called by muse, mutect2
- TRIB1 | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 109/637 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61335626; called by muse, mutect2, varscan2
- VCAN | c.8539A>T p.S2847C | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99424619; called by muse, mutect2
- ZNF385D | c.164C>A p.A55E | Missense Mutation (SNP) | VAF 37/649 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV55753651, COSV55768121; called by muse, mutect2
- ZNF721 | c.971G>T p.G324V (on ENST00000338977; = p.G336V on NM_133474.4) | Missense Mutation (SNP) | VAF 27/402 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.312); catalogued as COSV59090057; called by muse, mutect2
- A2M | c.336A>T p.Q112H | Missense Mutation (SNP) | VAF 29/500 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ADGRA3 | c.1978G>T p.G660* | Nonsense Mutation (SNP) | VAF 42/532 reads (8%) | called by muse, mutect2
- AEBP1 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.03); called by muse, mutect2
- ALLC | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 38/602 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKS1B | c.2725G>C p.G909R (on ENST00000547776 / NM_152788.4; = p.G135R on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APCDD1 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- BATF | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2, varscan2
- BRD4 | c.3143A>C p.H1048P | Missense Mutation (SNP) | VAF 20/397 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.158); called by muse, mutect2
- CD93 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH12 | c.2267C>A p.S756Y | Missense Mutation (SNP) | VAF 55/682 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CDH9 | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 42/726 reads (6%) | called by muse, mutect2
- CEACAM5 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 26/478 reads (5%) | called by muse, mutect2
- CHD7 | c.6439G>T p.A2147S | Missense Mutation (SNP) | VAF 184/1063 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL5A2 | c.1564-1G>T p.X522_splice | Splice Site (SNP) | VAF 60/1000 reads (6%) | called by muse, mutect2
- COL9A1 | c.659T>A p.L220Q | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DDR2 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 105/1024 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by muse, varscan2
- DIO2 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 36/405 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- DNAH12 | c.7157C>T p.P2386L (on ENST00000351747; = p.P3254L on NM_001366028.2) | Missense Mutation (SNP) | VAF 19/366 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); called by muse, mutect2
- DOCK2 | c.2620G>T p.D874Y | Missense Mutation (SNP) | VAF 50/544 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2
- FAM149A | c.1057G>T p.A353S (on ENST00000356371 / NM_001367768.2; = p.A62S on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- FAM171A1 | c.2221G>C p.D741H | Missense Mutation (SNP) | VAF 30/575 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBXO7 | c.833A>T p.Q278L | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.11); called by muse, mutect2
- FLRT2 | c.1322G>T p.W441L | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FTH1 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 68/928 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- GALC | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 74/989 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- GATA5 | c.1160G>C p.R387P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, varscan2
- GPR119 | c.371C>A p.A124D | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.305); called by muse, mutect2
- GRIK2 | c.926C>A p.S309* | Nonsense Mutation (SNP) | VAF 22/291 reads (8%) | called by muse, mutect2
- GUCA2B | c.173A>T p.Q58L | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.239); called by muse, mutect2
- HHIPL2 | c.1806-1G>C p.X602_splice | Splice Site (SNP) | VAF 34/416 reads (8%) | called by muse, mutect2
- HK3 | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- HPS5 | c.340del p.Q114Kfs*27 | Frame Shift Del (DEL) | VAF 26/261 reads (10%) | called by mutect2, pindel*
- HPSE2 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 68/823 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- HYDIN | c.13475C>G p.A4492G | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2
- IMPG1 | c.414T>G p.F138L | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- INVS | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 42/454 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- IQCF1 | c.464A>G p.Q155R | Missense Mutation (SNP) | VAF 42/540 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KHDC1 | c.539G>T p.R180L (on ENST00000370384 / NM_001251874.2; = p.R107L on NM_030568.5) | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- KRTAP10-7 | c.966C>A p.C322* | Nonsense Mutation (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- LHFPL4 | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAST3 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 20/447 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2
- MICAL1 | c.1789C>A p.P597T | Missense Mutation (SNP) | VAF 27/289 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2
- MYLK3 | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- OR4C15 | c.199C>A p.L67M (on ENST00000314644; = p.L13M on NM_001001920.2) | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR5J2 | c.870C>A p.H290Q | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- OTOG | c.3457C>A p.L1153I | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OTOG | c.5967C>G p.D1989E | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- P2RY10 | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 48/802 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.06); called by muse, mutect2
- PCDH11X | c.3688G>T p.A1230S | Missense Mutation (SNP) | VAF 129/1432 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); called by muse, mutect2
- PHLDB3 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PLCB1 | c.1079T>C p.V360A | Missense Mutation (SNP) | VAF 65/741 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- PLEKHB2 | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 38/660 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- PNPLA6 | c.3943G>C p.G1315R (on ENST00000414982 / NM_001166111.2; = p.G1267R on NM_006702.5) | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- POLR1B | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 48/738 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM41 | c.943A>T p.N315Y | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- RNF128 | c.805-1G>C p.X269_splice (on ENST00000255499 / NM_194463.2; = p.X243_splice on NM_024539.3) | Splice Site (SNP) | VAF 33/454 reads (7%) | called by muse, mutect2
- RNF180 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.133); called by muse, mutect2
- RP2 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2
- RPS6KA2 | c.1744-1G>C p.X582_splice | Splice Site (SNP) | VAF 24/325 reads (7%) | called by muse, mutect2
- RSBN1 | c.1594G>T p.V532L | Missense Mutation (SNP) | VAF 54/656 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- RTL1 | c.2087A>T p.E696V | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- SF3A1 | c.500T>G p.V167G | Missense Mutation (SNP) | VAF 44/486 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SFN | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- SGK2 | c.148G>T p.V50F | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2
- SH2D1A | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 41/554 reads (7%) | called by muse, mutect2
- SLC17A8 | c.1606C>A p.H536N | Missense Mutation (SNP) | VAF 21/568 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- SPEG | c.6789G>C p.Q2263H | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.436); called by muse, mutect2
- SYT6 | c.1365A>T p.R455= (on ENST00000610222 / NM_001366225.1; = p.R370= on NM_205848.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- TBL1X | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 9/137 reads (7%) | PolyPhen benign (0); called by muse, mutect2
- TH | c.785C>T p.T262I (on ENST00000381178 / NM_199292.3; = p.T231I on NM_000360.4) | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TMBIM1 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2
- TRBV4-2 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 26/419 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM38 | c.584A>T p.K195M | Missense Mutation (SNP) | VAF 60/678 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- TSHZ3 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTLL2 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.333); called by muse, mutect2
- UBE4B | c.2871G>T p.E957D (on ENST00000343090 / NM_001105562.3; = p.E828D on NM_006048.5) | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2
- UBP1 | c.1243A>G p.I415V | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2
- UNC79 | c.7289C>G p.P2430R (on ENST00000393151 / NM_001346218.2; = p.P2253R on NM_020818.5) | Missense Mutation (SNP) | VAF 31/638 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.047); called by muse, mutect2
- USP29 | c.2598G>T p.E866D | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2
- VNN1 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VPS13D | c.7941G>T p.E2647D | Missense Mutation (SNP) | VAF 51/794 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.022); called by muse, mutect2
- WAS | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.75); called by muse, mutect2
- WDR7 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 42/762 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- YPEL2 | c.118-1G>T p.X40_splice | Splice Site (SNP) | VAF 31/431 reads (7%) | called by muse, mutect2
- ZFP82 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- ZFYVE1 | c.259A>T p.R87W | Missense Mutation (SNP) | VAF 85/862 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.498); called by muse, mutect2
- ZFYVE16 | c.3242A>G p.Y1081C | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2
- ZFYVE26 | c.887-1G>C p.X296_splice | Splice Site (SNP) | VAF 25/614 reads (4%) | called by muse, mutect2
- ZNF530 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); called by muse, mutect2
- ZNF728 | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.849); called by muse, mutect2
- AHNAK2 | c.3108C>A p.S1036= | Silent (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- APOB | c.612C>T p.S204= | Silent (SNP) | VAF 48/928 reads (5%) | called by muse, mutect2
- ARHGEF10L | c.1095C>T p.R365= | Silent (SNP) | VAF 24/262 reads (9%) | catalogued as rs745373575; called by muse, mutect2
- CFAP47 | c.8808G>T p.V2936= | Silent (SNP) | VAF 36/330 reads (11%) | called by muse, mutect2, varscan2
- COL9A3 | c.1530G>A p.T510= | Silent (SNP) | VAF 32/391 reads (8%) | catalogued as rs753631418; called by muse, mutect2
- CSMD3 | c.759C>A p.S253= | Silent (SNP) | VAF 102/659 reads (15%) | catalogued as COSV99821813; called by muse, mutect2, varscan2
- FAM90A26 | c.366C>A p.S122= | Silent (SNP) | VAF 101/688 reads (15%) | called by muse, mutect2, varscan2
- FZD10 | c.478C>A p.R160= | Silent (SNP) | VAF 8/90 reads (9%) | called by mutect2, varscan2
- GAB1 | c.1917A>G p.P639= | Silent (SNP) | VAF 24/233 reads (10%) | called by muse, mutect2, varscan2
- GRID1 | c.276G>A p.T92= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs370422959; called by muse, mutect2, varscan2
- KCNH5 | c.2094C>G p.L698= | Silent (SNP) | VAF 21/237 reads (9%) | catalogued as COSV59769508; called by muse, mutect2
- MUC16 | c.24423C>G p.V8141= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as COSV67466886; called by muse, mutect2, varscan2
- NLRP1 | c.549G>A p.L183= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as rs1277527055; called by muse, mutect2
- NUP62CL | c.297C>A p.A99= | Silent (SNP) | VAF 27/310 reads (9%) | called by muse, mutect2
- OR10T2 | c.765C>A p.A255= | Silent (SNP) | VAF 39/424 reads (9%) | catalogued as rs562232494; called by muse, mutect2
- OR2T2 | c.945C>T p.I315= | Silent (SNP) | VAF 96/996 reads (10%) | catalogued as rs375267704; called by muse, varscan2
- PLCB4 | c.2935C>T p.L979= | Silent (SNP) | VAF 18/304 reads (6%) | catalogued as COSV99595441; called by muse, mutect2
- PLEKHS1 | c.1089T>C p.H363= | Silent (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- PRG4 | c.3096T>C p.T1032= | Silent (SNP) | VAF 27/1065 reads (3%) | called by muse, mutect2
- PRX | c.2157C>T p.V719= | Silent (SNP) | VAF 34/574 reads (6%) | catalogued as rs267605485; called by muse, mutect2
- RBBP6 | c.1530A>G p.K510= | Silent (SNP) | VAF 61/386 reads (16%) | catalogued as rs140015778; called by muse, mutect2, varscan2
- SEMA3D | c.649C>A p.R217= | Silent (SNP) | VAF 38/636 reads (6%) | catalogued as COSV52396179, COSV52397497; called by muse, mutect2
- SHCBP1L | c.1071C>A p.R357= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- TPM3 | c.283C>T p.L95= | Silent (SNP) | VAF 40/891 reads (4%) | called by muse, mutect2
- TUBA3C | c.717G>T p.T239= | Silent (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-7706A>T | Intron (SNP) | VAF 18/251 reads (7%) | called by muse, mutect2
- ARPP19P2 | n.239C>A | RNA (SNP) | VAF 17/416 reads (4%) | called by muse, mutect2
- BHLHE22 | c.*36C>G | 3'UTR (SNP) | VAF 75/465 reads (16%) | called by muse, mutect2, varscan2
- CD84 | c.778+34G>T | Intron (SNP) | VAF 64/478 reads (13%) | called by muse, mutect2, varscan2
- CEP170 | c.1272+86G>T | Intron (SNP) | VAF 72/695 reads (10%) | called by muse, mutect2, varscan2
- CES5A | c.-5G>T | 5'UTR (SNP) | VAF 14/439 reads (3%) | catalogued as rs1163474425; called by muse, mutect2
- EMC2 | c.363+19T>C | Intron (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- LRIG1 | c.1160+942C>G | Intron (SNP) | VAF 18/337 reads (5%) | called by muse, mutect2
- MARCHF1 | c.-322-85870A>T | Intron (SNP) | VAF 46/599 reads (8%) | called by muse, mutect2
- OFCC1 | n.305A>T | RNA (SNP) | VAF 27/398 reads (7%) | called by muse, mutect2
- OSGIN1 | n.600+2010G>C | Intron (SNP) | VAF 16/232 reads (7%) | catalogued as rs1378820730; called by muse, mutect2
- RIOK1 | c.1389+31G>T | Intron (SNP) | VAF 19/286 reads (7%) | called by muse, mutect2
- SMG1P6 | n.2348C>T | RNA (SNP) | VAF 26/238 reads (11%) | called by mutect2, varscan2
- SPATA31C1 | n.3636G>T | RNA (SNP) | VAF 82/806 reads (10%) | called by muse, mutect2, varscan2
- SRPK3 | chrX:153780330 C>A | 5'Flank (SNP) | VAF 36/408 reads (9%) | called by muse, mutect2
- TSSC4 | c.-2G>T | 5'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- USH1C | c.1647-48G>A | Intron (SNP) | VAF 32/386 reads (8%) | catalogued as rs557462431; called by muse, mutect2
- Unknown | chr21:16071257 G>T | IGR (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- YPEL2 | c.117+23C>T | Intron (SNP) | VAF 44/458 reads (10%) | catalogued as rs1365150734; called by muse, mutect2
- ZNF165 | chr6:28091360 G>A | 3'Flank (SNP) | VAF 26/458 reads (6%) | catalogued as rs928311895; called by muse, mutect2
